Somatic mutation profile of tumor specimen HTMCP-03-06-02362-01A (aliquot HTMCP-03-06-02362-01A-01D-9392) from CGCI case HTMCP-03-06-02362, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02362-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e49e79c-4ca2-47f9-ae0a-c31acc99fc60.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02362-10A (Blood Derived Normal), aliquot HTMCP-03-06-02362-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59a1e784-ec12-49e8-a7b2-22373a7789a9

The open-access MAF lists 91 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 21, Nonsense Mutation 7, Intron 5, Frame Shift Del 3, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- POLG | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs1567192879, CM078477, COSV99175042; ClinVar: pathogenic; called by muse, mutect2
- ATRX | c.5071C>G p.Q1691E | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV64877327, COSV64877917; called by muse, mutect2, varscan2
- CATSPERE | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369590534; called by muse, mutect2, varscan2
- CHL1 | c.1597G>A p.E533K (on ENST00000397491 / NM_001253387.1; = p.E549K on NM_006614.4) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV56592860; called by muse, mutect2, varscan2
- COL11A1 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs551653403; called by muse, mutect2, varscan2
- CSMD3 | c.2972G>C p.R991P (on ENST00000297405 / NM_001363185.1; = p.R887P on NM_052900.3) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52168720; called by muse, varscan2
- DIAPH3 | c.1969C>T p.H657Y (on ENST00000400324 / NM_001042517.2; = p.H394Y on NM_030932.3) | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs771360069; called by muse, mutect2
- DLGAP2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760292969, COSV70098570; called by muse, mutect2
- DNAH10 | c.4816G>A p.E1606K (on ENST00000409039; = p.E1545K on NM_207437.3) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs200756084; called by muse, mutect2, varscan2
- DNAH5 | c.11501G>A p.R3834H | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs139914691; called by muse, mutect2
- DNAJC6 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs947409137, COSV54779273; called by muse, mutect2, varscan2
- FAM47A | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs17855514, COSV60495273, COSV60497171; called by muse, varscan2
- FLG | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1310447389, COSV100912143; called by muse, mutect2, varscan2
- FRMPD2 | c.2220G>A p.M740I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59715724; called by muse, varscan2
- GGCX | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as COSV52089991, COSV52090498; called by muse, mutect2
- GRM3 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64471938; called by muse, mutect2, varscan2
- GTF2F1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs148016023; called by muse, mutect2, varscan2
- KIAA0408 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374099610; called by muse, mutect2, varscan2
- MMP16 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99690364; called by muse, mutect2, varscan2
- MYH6 | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775843647, COSV104422401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NINL | c.3234G>C p.L1078F | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.404); catalogued as rs772296389, COSV54003247, COSV99625943; called by muse, mutect2, varscan2
- PHKA2 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs757043355; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR1 | c.8159C>T p.S2720L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV62104818, COSV62108390; called by muse, mutect2
- STAB2 | c.4924G>C p.E1642Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV66344483; called by muse, mutect2, varscan2
- TENM2 | c.6505C>T p.R2169W (on ENST00000518659 / NM_001122679.2; = p.R1930W on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756900207; called by muse, mutect2
- TLR8 | c.2269G>A p.E757K (on ENST00000218032 / NM_138636.5; = p.E775K on NM_016610.4) | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as COSV54317248; called by muse, mutect2, varscan2
- UBAP2 | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as rs1407980677, COSV62549266; called by muse, mutect2, varscan2
- UNC13C | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99512843; called by muse, mutect2, varscan2
- ZNF658 | c.2631_2632del p.K880Tfs*3 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | catalogued as rs775652828; called by mutect2, varscan2
- ADNP | c.485A>G p.Q162R | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AKAP11 | c.2588C>T p.S863L | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ATAD5 | c.3476C>G p.S1159C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf16 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- CBLB | c.1478_1480del p.Q493del | In Frame Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- CELSR3 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEMIP | c.1978A>G p.I660V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD6 | c.3802G>A p.D1268N | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- COL7A1 | c.5113C>T p.P1705S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CTC1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF4A2 | c.1080-1G>A p.X360_splice | Splice Site (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- EMILIN2 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FARP2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- FLG | c.11879C>G p.S3960C | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GLYR1 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GOLGA3 | c.2934G>A p.M978I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GPRC6A | c.2750C>T p.T917I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGS | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- KIAA1549 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1B | c.3914C>A p.T1305K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH1 | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PHF12 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | called by muse, varscan2
- PPP1R12A | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- PUM1 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- RB1CC1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3D21 | c.1729G>C p.E577Q (on ENST00000453908 / NM_001162530.2; = p.E466Q on NM_024676.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SMC6 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 83/250 reads (33%) | called by muse, mutect2, varscan2
- SNTB1 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYNGAP1 | c.3867G>C p.K1289N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TCEAL4 | c.198del p.S67Vfs*30 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- TGFBR3 | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UTRN | c.5785G>A p.E1929K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ZNF521 | c.3404del p.G1135Dfs*2 | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | called by mutect2, pindel, varscan2
- ZSWIM6 | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP13A4 | c.327C>T p.L109= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- BFAR | c.942C>T p.I314= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as rs376735482; called by muse, mutect2
- CSMD1 | c.9603G>A p.T3201= (on ENST00000520002; = p.T3200= on NM_033225.6) | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs764774756, COSV59360788; called by muse, mutect2, varscan2
- DSCAM | c.3411G>A p.L1137= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- EPHA5 | c.3048G>A p.Q1016= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV56633729; called by muse, mutect2, varscan2
- FAM47A | c.1554C>T p.R518= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs866449357, COSV60497385; called by muse, varscan2
- GCN1 | c.3852C>G p.L1284= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs368296688; called by muse, mutect2, varscan2
- L1CAM | c.210G>A p.T70= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV62826825; called by muse, mutect2, varscan2
- MARCHF6 | c.2203C>T p.L735= | Silent (SNP) | VAF 71/207 reads (34%) | called by muse, mutect2, varscan2
- MIA2 | c.801G>C p.L267= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- MYH9 | c.5193C>T p.I1731= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs754110601; called by muse, mutect2, varscan2
- ODF2 | c.1077G>A p.E359= (on ENST00000434106 / NM_153433.2; = p.E335= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100654923; called by muse, mutect2, varscan2
- PAX1 | c.333C>T p.N111= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV101270260; called by muse, mutect2, varscan2
- PCDH19 | c.3045C>T p.F1015= (on ENST00000373034 / NM_001184880.2; = p.F967= on NM_020766.3) | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs746702101, COSV55261491; called by muse, mutect2, varscan2
- RAC1 | c.531C>G p.L177= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV61821594; called by muse, mutect2, varscan2
- RAVER2 | c.1737C>T p.L579= (on ENST00000294428 / NM_001366165.1; = p.L566= on NM_018211.4) | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- SZT2 | c.10008C>T p.S3336= (on ENST00000634258 / NM_001365999.1; = p.S3279= on NM_015284.4) | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- TRPS1 | c.1011C>T p.F337= (on ENST00000220888 / NM_001330599.2; = p.F350= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/315 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.486G>A p.L162= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- UBE3A | c.2142C>T p.V714= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- UNC13C | c.582C>T p.V194= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV52883668; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2114C>T | Intron (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10360+2887G>A | Intron (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- UBR2 | c.1281+134G>C | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- UNK | c.104+7337G>C | Intron (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1716-9298G>A | Intron (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
